Somatic mutation profile of tumor specimen C3N-00435-05 (aliquot CPT0017850009) from CPTAC case C3N-00435, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 72.8 years (26,583 days).
Specimen C3N-00435-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8377b473-bce6-4657-9c16-dfad518f2a73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00435-71 (Blood Derived Normal), aliquot CPT0022960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/406cb8c8-0761-42cf-b97e-2d8eea2afc55

The open-access MAF lists 76 somatic variants for this specimen: 55 protein-altering or splice-affecting, 8 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Frame Shift Del 10, Silent 8, Intron 7, In Frame Del 3, 3'Flank 3, 5'UTR 1, Splice Site 1, 5'Flank 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 17/107 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANO6 | c.2612A>T p.K871I | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs777763824; called by muse, mutect2, varscan2
- BIRC6 | c.13921C>A p.P4641T | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as COSV101428224; called by muse, mutect2, varscan2
- DCAF15 | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.359); catalogued as COSV99586670; called by muse, mutect2, varscan2
- DCXR | c.145C>G p.R49G | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs376086551; called by muse, mutect2
- ESYT1 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs140189916; called by muse, mutect2, varscan2
- OR4C6 | c.557C>G p.A186G | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.4); catalogued as COSV58602768; called by muse, mutect2, varscan2
- PCDH12 | c.3503C>T p.T1168M | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs774266314; called by muse, mutect2, varscan2
- PGM1 | c.439A>C p.I147L | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV64300234, COSV64301652; called by muse, mutect2
- PLA2G7 | c.120C>A p.N40K | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs760872166; called by muse, mutect2, varscan2
- RGPD3 | c.3103G>T p.D1035Y | Missense Mutation (SNP) | VAF 30/449 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58739409; called by muse, mutect2
- TCF25 | c.1870del p.E624Rfs*13 | Frame Shift Del (DEL) | VAF 32/269 reads (12%) | catalogued as COSV99643407; called by mutect2, pindel, varscan2
- ZNF624 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as rs777042861, COSV60941478; called by muse, mutect2, varscan2
- ABCA8 | c.1963T>A p.C655S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS16 | c.3628T>C p.F1210L | Missense Mutation (SNP) | VAF 31/519 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2
- ATP7B | c.1167A>T p.Q389H | Missense Mutation (SNP) | VAF 94/745 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- B3GNT5 | c.984T>A p.D328E | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BDP1 | c.1277_1284del p.S426* | Frame Shift Del (DEL) | VAF 14/141 reads (10%) | called by mutect2, pindel
- CCDC47 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- CDC14C | c.665_682del p.G222_A227del (on ENST00000428251; = p.G115_A120del on NM_152627.3) | In Frame Del (DEL) | VAF 23/131 reads (18%) | called by mutect2, pindel, varscan2
- CETN3 | c.170del p.L57Wfs*5 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | called by mutect2, pindel, varscan2
- CTNNA3 | c.1166T>A p.F389Y | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DHX8 | c.3274G>A p.D1092N | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by mutect2, varscan2
- EEA1 | c.60A>T p.L20F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ERCC6L | c.1922A>C p.Q641P | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FREM1 | c.5569C>A p.P1857T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, varscan2
- FRYL | c.687del p.R230Efs*2 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- HDAC8 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HELZ | c.3563C>G p.T1188S | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); called by muse, mutect2
- HS6ST3 | c.1175_1177del p.G392del | In Frame Del (DEL) | VAF 31/223 reads (14%) | called by mutect2, pindel, varscan2
- KIF16B | c.3667C>G p.R1223G | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC37B | c.1682_1683del p.N561Ifs*10 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | called by mutect2, varscan2
- MAGI3 | c.3797G>A p.C1266Y | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MAGOHB | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MB21D2 | c.1070T>C p.F357S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- NAT8 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NMNAT1 | c.43_45delinsC p.G15Lfs*14 | Frame Shift Del (DEL) | VAF 36/226 reads (16%) | called by pindel, varscan2*
- OBSCN | c.10402A>T p.M3468L | Missense Mutation (SNP) | VAF 27/460 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2
- PADI1 | c.958A>C p.K320Q | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.015); called by muse, mutect2
- PCDHB6 | c.288_301del p.S97Cfs*26 | Frame Shift Del (DEL) | VAF 39/267 reads (15%) | called by mutect2, pindel, varscan2
- PIGS | c.994G>C p.A332P | Missense Mutation (SNP) | VAF 52/299 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PIK3C2G | c.2316_2320del p.F773Rfs*6 (on ENST00000676171; = p.F732Rfs*6 on NM_004570.5) | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- PNLIPRP1 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POLG | c.1434-2A>T p.X478_splice | Splice Site (SNP) | VAF 139/879 reads (16%) | called by muse, mutect2, varscan2
- PRSS12 | c.1721G>A p.R574K | Missense Mutation (SNP) | VAF 65/519 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PRSS54 | c.500_503del p.S167Yfs*12 | Frame Shift Del (DEL) | VAF 51/339 reads (15%) | called by mutect2, pindel
- PTPN2 | c.338A>T p.N113I | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RLF | c.1240C>T p.L414F | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RPRD2 | c.396del p.Y133Tfs*5 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel, varscan2
- SAMD14 | c.839A>G p.D280G (on ENST00000330175 / NM_001257359.2; = p.D308G on NM_174920.4) | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC4A1AP | c.7_12del p.A3_P4del | In Frame Del (DEL) | VAF 18/176 reads (10%) | called by mutect2, pindel, varscan2
- SPEF2 | c.2744C>A p.P915H | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2
- TXNIP | c.145T>G p.C49G | Missense Mutation (SNP) | VAF 102/649 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZCCHC10 | c.378G>T p.E126D (on ENST00000509437 / NM_001300818.3; = p.E104D on NM_017665.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2
- ZNF219 | c.1825C>A p.P609T | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CDCA7 | c.165G>A p.R55= (on ENST00000347703 / NM_145810.3; = p.R134= on NM_031942.5) | Silent (SNP) | VAF 47/284 reads (17%) | catalogued as COSV60720633; called by muse, mutect2, varscan2
- CYP1A1 | c.930C>T p.I310= | Silent (SNP) | VAF 20/218 reads (9%) | catalogued as rs1314957260; called by muse, mutect2
- ERRFI1 | c.1260C>A p.G420= | Silent (SNP) | VAF 23/398 reads (6%) | catalogued as rs373519813; called by muse, mutect2
- KMT5B | c.201A>G p.V67= | Silent (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- OPHN1 | c.297T>C p.N99= | Silent (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- PLXND1 | c.3126G>C p.P1042= | Silent (SNP) | VAF 40/247 reads (16%) | catalogued as COSV100139096; called by muse, mutect2, varscan2
- PPP1R12B | c.957T>A p.I319= | Silent (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- RTEL1 | c.96G>A p.L32= | Silent (SNP) | VAF 74/348 reads (21%) | catalogued as rs767851345; called by muse, mutect2, varscan2
- AAAS | c.997-45C>G | Intron (SNP) | VAF 74/584 reads (13%) | called by muse, mutect2, varscan2
- AKAP9 | c.5162+32G>A | Intron (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- CCER1 | chr12:90947963 C>T | 3'Flank (SNP) | VAF 38/247 reads (15%) | catalogued as rs752615159; called by muse, mutect2, varscan2
- FAM182A | n.1061T>G | RNA (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2, varscan2
- FAM53C | c.-2T>C | 5'UTR (SNP) | VAF 50/351 reads (14%) | called by muse, mutect2, varscan2
- OSGIN1 | n.600+2018T>C | Intron (SNP) | VAF 36/286 reads (13%) | catalogued as rs939033738; called by muse, mutect2
- R3HDML | chr20:44355776 C>T | 3'Flank (SNP) | VAF 61/712 reads (9%) | called by muse, mutect2
- RPLP1 | chr15:69458714 del T | 3'Flank (DEL) | VAF 16/114 reads (14%) | called by mutect2, pindel, varscan2
- SART3 | c.1363+9G>T | Intron (SNP) | VAF 48/304 reads (16%) | catalogued as rs372012268; called by muse, mutect2, varscan2
- SHFL | c.196-356A>C | Intron (SNP) | VAF 73/503 reads (15%) | called by muse, mutect2, varscan2
- TNRC18 | c.6148-19C>G | Intron (SNP) | VAF 88/313 reads (28%) | called by muse, mutect2, varscan2
- UBE2D2 | c.24+466G>T | Intron (SNP) | VAF 42/235 reads (18%) | called by muse, mutect2, varscan2
- ZNF205 | chr16:3110831 G>T | 5'Flank (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
